Surgical pathology report (de-identified scan), TCGA case TCGA-US-A77J, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Garvan Institute of Medical Research, specimen TCGA-US-A77J-01A (Primary Tumor).

[page 1 of 5]
Page 1

ICD O-3

Adenocarcinoma, duct NOS
8500/3
Site: Pancreas head
C25.0

JW 8/20/13

INTERPRETATION AND DIAGNOSIS:

1. PANCREATIC NECK MARGIN (EXCISION): CHRONIC PANCREATITIS WITH LYMPHOID AGGREGATES. NEGATIVE FOR TUMOR.

2. PANCREAS, DUODENUM, AND GALLBLADDER (PANCREATODUODENECTOMY AND CHOLECYSTECTOMY):

SPECIMEN TYPE:

Pylorus-sparing pancreaticoduodenectomy, with cholecystectomy.

SITE OF ORIGIN:

Pancreas.

TUMOR SITE:

Pancreatic head.

HISTOLOGIC TYPE:

Ductal adenocarcinoma.

TUMOR SIZE:

Greatest dimension: 2.5 cm.

HISTOLOGIC GRADE:

G2: Moderately differentiated.

LYMPH NODES (INCLUDES ALL PARTS):

Metastatic carcinoma in four (4) of twenty (20) lymph nodes.

LOCAL EXTENSION:

Wall of duodenum, distal common bile duct, and ampulla.

EXTENT OF INVASION (7th Edition AJCC)

PRIMARY TUMOR:

pT3: Extends beyond the pancreas, but without involving the celiac axis or SMA.

(Continued on next page.)

[page 2 of 5]
MARGINS:
Margins uninvolved. Distance of invasive carcinoma from closest margin (uncinate margin) is <1 mm.

VENOUS (LARGE) VESSEL INVASION:
Present.

PERINEURAL INVASION:
Present.

ADDITIONAL PATHOLOGIC FINDINGS:
Chronic pancreatitis with lymphoid aggregates, gallbladder with adenomyoma, and chronic cholecystitis.

Note: This case was shown at the

* Electronic signature (

=====

GROSS DESCRIPTION

(Continued on next page.)

[page 3 of 5]
PART #1: FS: PANCREATIC NECK MARGIN

FROZEN SECTION DIAGNOSIS:

Staff Pathologist:

Other Pathologists / PAs:

FS: Pancreatic neck margin: Negative for tumor.

Dictated by:

The specimen is received fresh for frozen section, labeled with the patient's name, ' ', and designated 'pancreatic neck margin.' The specimen consists of a single piece of irregular, unoriented, irregular, tissue measuring 1.6 x 1.6 x 0.3 cm. The specimen is submitted in its entirety for frozen section and the remainder is submitted for permanent, therefore the specimen is entirely submitted.

SUMMARY OF SECTIONS

1 - FSC - 1 (FROZEN SECTION, PANCREATIC NECK MARGIN)
1 - TOTAL - 1

(Continued on next page.)

[page 4 of 5]
PART #2: FS: GALLBLADDER AND WHIPPLE ()

FROZEN SECTION DIAGNOSIS:

FS: Gallbladder and Whipple: 2.5 cm adenocarcinoma centered in the pancreas, <0.5 mm from uncinate margin, common bile duct margin is negative. Proximal duodenal margin is negative. Incidentally identified two lymph nodes with metastasis (2/2).

The specimen is received fresh for frozen section, labeled with the patient's name, . and designated 'gallbladder and Whipple.' The surgeon has oriented the specimen such that a stitch is on the uncinate process. The specimen consists of a grossly recognizable pancreas head and attached duodenum. The pancreas measures 5.0 x 4.0 x 2.0 cm and the duodenum measures 16.0 cm in length by 3.0 cm in average diameter. The pancreatic neck margin is identified and shaved for permanent section. The common bile duct is dilated with an approximate diameter of 1.0 cm. In addition, a stent has been placed in the common bile duct. The common bile duct margin is also shaved for frozen section. The uncinate margin is cut and submitted for frozen section. The pancreas is then serially sectioned to reveal a small portion of grossly unremarkable yellow-tan lobulated parenchyma, however the majority of the submitted pancreas is encompassed by a firm, white, ill-defined tumor which measures 2.5 cm in greatest dimension. A representative section of this tumor is also submitted for frozen section. The proximal and distal duodenal margins are shaved and the duodenum is opened to reveal tan mucosa with normal folds. A small area of submucosal hemorrhage is noted in the duodenum which measures less than 0.5 cm in greatest dimension. Aside from this hemorrhage, no other lesions, masses or other abnormalities are noted in the duodenal mucosa. The common bile duct is opened to the ampulla of Vater to reveal white-tan mucosa and a dilated lumen, but no gross

(Continued on next page.)

[page 5 of 5]
abnormalities after the stent is removed. Separately received is a gallbladder which measures 9.5 cm in length by 3.5 cm in maximum diameter. Opening the gallbladder reveals minimal bile and no stones are present. The serosal surface of the gallbladder is green-pink and shiny with no external abnormalities. The gallbladder mucosa is brown-red and velvety with no lesions or masses noted. There is an area of wall thickening in the distal fundus with a dimension of 2.2 x 2.0 x 2.0 cm. Otherwise, the gallbladder is grossly unremarkable. Representative sections of the pancreas, duodenum, common bile duct, tumor and gallbladder are submitted. In addition, the peripancreatic soft tissue is submitted entirely.

SUMMARY OF SECTIONS

1 - FSC T - 1 (FROZEN SECTION CONTROL, TUMOR)
1 - FSC UM - 1 (FROZEN SECTION CONTROL, UNCINATE MARGIN)
1 - FSC CBD - 1 (FROZEN SECTION CONTROL, COMMON BILE DUCT MARGIN)
1 - FSC UM - 1 (FROZEN SECTION CONTROL, PROXIMAL MARGIN)
1 - PANM - 1 (PANCREATIC NECK MARGIN)
2 - P1,P2 - 1 EACH (UNINVOLVED PANCREAS)
1 - DM - 1 (DISTAL MARGIN)
2 - T1,T2 - 1 EACH (TUMOR IN RELATION TO COMMON BILE DUCT)
2 - T3,T4 - 1 EACH (TUMOR IN RELATION TO DUODENUM)
1 - AMP - 1 (AMPULLA)
2 - CBD1,CBD2-1 EACH (COMMON BILE DUCT)
1 - DUOD - 2 (DUODENUM)
1 - GB - 3 (GALLBLADDER)
2 - PST1,PST2-1 EACH (1 PERIPANCREATIC LN, BISECTED)
3 - PST3-PST5-1 EACH (PERIPANCREATIC SOFT TISSUE)
4 - PST6-PST9-3 EACH (PERIPANCREATIC SOFT TISSUE)
26 - TOTAL - 37

(End of Report)

printed

Source: NCI Genomic Data Commons file f1205650-2da4-4500-b2e3-5505d5b091f0 (TCGA-US-A77J.D16151A6-7021-48DB-A29D-79538DCD2B1D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).